Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5009, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5009-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

TCGA-BP-5009

Clinical Diagnosis & History:

Year old male with history of hairy cell leukemia as a child, NED. Incidentally found with a 6 x 8 cm left renal mass.

Specimens Submitted:

1: Kidney, left, partial nephrectomy

DIAGNOSIS:

1. Kidney, left, partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 5.7 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Small vessel angiolymphatic invasion also not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Cortical scar, and interstitial chronic and focally granulomatous inflammation

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	
	RECUT	
	RECUT	
	RECUT	
	RECUT	
	RECUT	

Gross Description:

1). The specimen is received fresh for frozen section consultation and is labeled "left renal tumor stitch marks deep margin". It consists of a 8.2x6.2x5.0cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a well circumscribed, variegated golden-yellow to tan mass lesion measuring 5.7 x 5.3 x 4.0 cm. Areas of hemorrhage, necrosis, and probable myxoid degeneration are identified. The tumor is adhered to the perinephric adipose tissue, but does not extend through it. The clearance from the parenchymal resection margin is 0.1cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for [REDACTED] Photographs are taken.

Summary of sections:

FSC - frozen section control

T - tumor

M - margin

R - representative sections kidney

TF - tumor to capsule/fat

Summary of Sections:

Part 1: Kidney, left, partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
2	m	2
1	r	1
4	t	4
2	tf	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: Left renal tumor [REDACTED] DESIGNATED MARGIN AT STITCH IS FREE OF TUMOR.
PERMANENT DIAGNOSIS: [REDACTED] SAME

Source: NCI Genomic Data Commons file a3dafc27-0d2c-4245-8bb5-ca42bed0ccfb (TCGA-BP-5009.4268CEEB-4906-412A-9DAD-8FC041C9C6F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).